Gene-level copy-number profile of specimen HCM-BROD-0095-C15-85A from HCMI case HCM-BROD-0095-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 51.5 years (18,799 days).
Specimen HCM-BROD-0095-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9570b1c7-84b2-4279-ba1a-7b89b6b91231.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0095-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/8afa8464-b53b-4c0f-a61a-17ab40ac7dc7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,508; copy number 2: 36,240; copy number 3: 10,036; copy number 4: 4,250; copy number 5: 3,333; copy number 6: 513; copy number 7: 6; copy number 9: 26.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,878 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,177,234–112,707,434, 14 genes, copy number 6 (within-gene range 3–6): LINC02884, TXNP3, AL591521.1, CTTNBP2NL, MIR4256, WNT2B, AL354760.1, ST7L, CAPZA1, MRPL53P1, RNU7-70P, MOV10, AL603832.1, RHOC.
- chr1:119,596,167–200,860,704, 1,505 genes, copy number 5–7 (broad region; genes not listed).
- chr1:238,107,736–248,937,043, 249 genes, copy number 6 (broad region; genes not listed).
- chr2:207,529,737–207,769,906, 11 genes, copy number 9 (within-gene range 4–9): CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5.
- chr3:7,951,263–8,841,808, 10 genes, copy number 6 (within-gene range 4–6): LMCD1-AS1, AC018832.1, AC023481.1, RNU4ATAC17P, LMCD1, AC034187.1, SSUH2, OR7E122P, CAV3, OXTR.
- chr3:42,692,663–42,773,253, 4 genes, copy number 5 (within-gene range 4–5): HHATL, AC006059.3, HHATL-AS1, CCDC13.
- chr3:42,719,401–42,746,768, 2 genes, copy number 5: AC006059.4, CCDC13-AS1.
- chr3:43,079,232–43,106,079, 3 genes, copy number 5: POMGNT2, AC092042.1, AC092042.4.
- chr6:23,337,711–23,404,132, 1 gene, copy number 5: AL139231.1.
- chr6:32,032,713–32,036,258, 1 gene, copy number 5 (within-gene range 4–5): C4B-AS1.
- chr6:50,009,138–50,021,994, 1 gene, copy number 5: DEFB110.
- chr7:81,946,444–104,208,047, 430 genes, copy number 5–9 (broad region; genes not listed).
- chr8:112,148,742–145,066,685, 506 genes, copy number 5 (broad region; genes not listed).
- chr12:273,954–563,509, 4 genes, copy number 5–6: AC007406.4, KDM5A, CCDC77, B4GALNT3.
- chr17:26,981,694–31,095,450, 232 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:31,759,795–32,412,420, 35 genes, copy number 5: GPR160P2, AC007923.1, AC004253.2, COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5.
- chr20:30,214,765–64,327,972, 870 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,652. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
